Somatic mutation profile of tumor specimen 0DWWMV from CCDI case PBCPNH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Granulosa cell tumor, juvenile; Tissue or organ of origin: Ovary; Age at diagnosis: 16.4 years (6,008 days).
Specimen 0DWWMV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fa8abdd-9f32-4fd5-8504-b78c9aad64ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWWMF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d47a943c-0483-495f-bfa6-68ce02b97754

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Splice Site 1, Splice Region 1, 5'UTR 1, 5'Flank 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMOTL2 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 38/350 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs922364496; called by muse, mutect2
- RNF112 | c.1887G>T p.Q629H | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as rs1260006346; called by muse, mutect2
- SLC17A6 | c.131C>A p.T44K | Missense Mutation (SNP) | VAF 32/265 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as COSV54135674; called by muse, mutect2, varscan2
- TENM3 | c.4654G>T p.D1552Y | Missense Mutation (SNP) | VAF 49/429 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV69312457, COSV69312756; called by muse, mutect2, varscan2
- CACHD1 | c.1664+1G>A p.X555_splice | Splice Site (SNP) | VAF 68/575 reads (12%) | called by muse, mutect2, varscan2
- CCDC3 | c.550-6C>T | Splice Region (SNP) | VAF 16/346 reads (5%) | called by muse, mutect2
- CFAP47 | c.2214C>A p.S738R | Missense Mutation (SNP) | VAF 75/648 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.127); called by mutect2, varscan2
- ELK1 | c.68T>A p.I23N | Missense Mutation (SNP) | VAF 43/404 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ISL1 | c.1025T>A p.M342K | Missense Mutation (SNP) | VAF 57/497 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- KIAA0825 | c.932A>G p.K311R | Missense Mutation (SNP) | VAF 37/542 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2
- PPP1CA | c.870G>T p.M290I | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRQ | c.2366C>T p.S789F (on ENST00000616559; = p.S747F on NM_001145026.2) | Missense Mutation (SNP) | VAF 44/896 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- SIPA1L2 | c.4847C>A p.T1616K | Missense Mutation (SNP) | VAF 57/529 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SPAG17 | c.2784G>T p.K928N | Missense Mutation (SNP) | VAF 55/479 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ZXDA | c.1194G>T p.K398N | Missense Mutation (SNP) | VAF 45/429 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CWH43 | c.1011G>A p.K337= | Silent (SNP) | VAF 58/641 reads (9%) | called by muse, mutect2
- DQX1 | c.2139C>T p.P713= | Silent (SNP) | VAF 30/275 reads (11%) | called by muse, mutect2, varscan2
- MRPS17 | c.21C>T p.S7= | Silent (SNP) | VAF 53/610 reads (9%) | catalogued as rs868749537, COSV53392985; called by muse, mutect2
- SELENOV | c.120G>T p.R40= | Silent (SNP) | VAF 13/180 reads (7%) | called by muse, mutect2
- CHEK1 | chr11:125625811 C>T | 5'Flank (SNP) | VAF 37/336 reads (11%) | catalogued as rs1277851631; called by muse, mutect2, varscan2
- DNAJC24 | c.-12C>G | 5'UTR (SNP) | VAF 16/384 reads (4%) | called by muse, mutect2
- SLC25A5 | c.599-38T>C | Intron (SNP) | VAF 26/239 reads (11%) | called by muse, mutect2
- SRRM4 | c.*38G>T | 3'UTR (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
